Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5L5, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5L5-01A (Primary Tumor).

Procedure: L adrenalectomy

Gross description: 8 x 4.5 x 2cm, tumor 2.5 x 2 x 2cm

Diagnosis: adrenocortical carcinoma, Pt3 PnX L0 V0 Pn0 R0

Reference Pathology:

Diagnosis: adrenocortical carcinoma, 3 per 10 hpf, unusual size and character, in light of absence of other primary tumor in this patient and tumor characteristics the diagnosis of adrenocortical carcinoma is confirmed

ICDO-3

Carcinoma, adrenal cortical
8370/3

Site: (C) Adrenal Gland
Cortex C94.0

gud 2/6/13

ICDPA Discrepancy		
Dual/Synchronous Malignancy Noted		

Source: NCI Genomic Data Commons file f0dec0c8-7c33-4104-965d-2de840e4fc33 (TCGA-OR-A5L5.A1989B2E-FB1F-420A-BF11-2C79F3E81884.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).